FM case AD11018 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/ecfd1cbf-6c53-49ee-a3fb-d6e1ce057a20

Female, 65.6 years: Serous carcinoma, NOS (ICD-O-3 8441/3) of the fallopian tube; metastasis biopsied or resected from the uterus. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
